Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3520, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3520-01A (Primary Tumor).

*** Diagnosis / Diagnoses: ***

- 1.: Adnexa (right) with a serous cystadenofibroma of the ovary, measuring 8 cm in diameter. Tube without relevant pathological findings.
2. (right hemicolectomy specimen) with an ulcerated colon carcinoma conforming to the histological type of a moderately differentiated colorectal adenocarcinoma, located 6 cm aboral to Bauhin's valve and with a greatest diameter of 3 cm. Invasive spread of tumor within all layers of the intestinal wall and as far as the neighboring fatty tissue. Appendix without relevant pathological findings.
Oral and aboral resection margins and large omentum tumor-free.
Twenty regional lymph nodes tumor-free with uncharacteristic reactive changes.

Tumor stage thus pT3 pN0 (0/20) L0, V0; G2.

Source: NCI Genomic Data Commons file c0dbb96d-be76-41bb-834f-7747bb0d7a5b (TCGA-AA-3520.1CCF52AC-3817-46AF-9DC6-A948F919A527.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).